Somatic mutation profile of tumor specimen TCGA-AO-A0J8-01A (aliquot TCGA-AO-A0J8-01A-21D-A045-09) from TCGA case TCGA-AO-A0J8, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 61.0 years (22,284 days).
Specimen TCGA-AO-A0J8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ced8ea0a-4b70-4ff1-a0f1-ec9b0ab41c0a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A0J8-10A (Blood Derived Normal), aliquot TCGA-AO-A0J8-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d8024de-4a2c-47af-92ba-8a85bb149bd8

The open-access MAF lists 29 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 6, Frame Shift Ins 2, Nonsense Mutation 2, Frame Shift Del 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADH1A | c.538G>C p.G180R | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52925384; called by muse, mutect2, varscan2
- CLMN | c.304A>G p.K102E | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as COSV54183895; called by muse, mutect2, varscan2
- FAAH | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54544692; called by muse, mutect2, varscan2
- FAM199X | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 64/205 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as COSV55434010; called by muse, mutect2, varscan2
- FLG | c.10246G>A p.E3416K | Missense Mutation (SNP) | VAF 339/743 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as rs140368354; called by muse, mutect2, varscan2
- GALNT17 | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.34); catalogued as COSV61169747; called by muse, mutect2
- MBD6 | c.2632C>T p.R878* | Nonsense Mutation (SNP) | VAF 5/11 reads (45%) | catalogued as COSV63074460; called by muse, mutect2, varscan2
- NDFIP1 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 215/616 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770674685, COSV54073869; called by muse, varscan2
- NR2E1 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV64562266; called by muse, mutect2, varscan2
- PDZD2 | c.194A>G p.E65G | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV56862936, COSV99223216; called by muse, mutect2, varscan2
- PNLIPRP1 | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.3); catalogued as COSV62612311; called by muse, mutect2, varscan2
- PSEN2 | c.811A>G p.K271E | Missense Mutation (SNP) | VAF 75/344 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV60916996; called by muse, mutect2, varscan2
- RDH10 | c.616G>A p.G206R | Missense Mutation (SNP) | VAF 17/266 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.142); catalogued as COSV99536067; called by muse, mutect2
- TRIM55 | c.131A>G p.H44R | Missense Mutation (SNP) | VAF 30/354 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99396477; called by muse, mutect2
- TSC22D1 | c.2062C>T p.Q688* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as COSV71775867; called by muse, mutect2, varscan2
- TYW1 | c.2072T>G p.F691C | Missense Mutation (SNP) | VAF 12/380 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100658342; called by muse, mutect2
- AMMECR1 | c.563_579del p.L188Hfs*5 | Frame Shift Del (DEL) | VAF 34/123 reads (28%) | called by mutect2, pindel, varscan2
- CDH1 | c.2121del p.P708Lfs*14 | Frame Shift Del (DEL) | VAF 23/50 reads (46%) | called by mutect2, pindel, varscan2
- POTEA | c.1197G>T p.K399N (on ENST00000519951 / NM_001005365.2; = p.K353N on NM_001002920.1) | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- RUNX1 | c.286dup p.D96Gfs*15 (on ENST00000344691 / NM_001001890.3; = p.D123Gfs*15 on NM_001754.5) | Frame Shift Ins (INS) | VAF 49/155 reads (32%) | called by mutect2, pindel, varscan2
- SRD5A2 | c.643dup p.A215Gfs*19 | Frame Shift Ins (INS) | VAF 34/100 reads (34%) | called by mutect2, pindel, varscan2
- ATP6V0A2 | c.1386G>A p.V462= | Silent (SNP) | VAF 54/181 reads (30%) | catalogued as COSV57750195; called by muse, mutect2, varscan2
- DACT1 | c.2247C>T p.Y749= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV60021764; called by muse, mutect2, varscan2
- DOCK11 | c.3360G>C p.L1120= | Silent (SNP) | VAF 80/245 reads (33%) | catalogued as COSV52242170; called by muse, mutect2, varscan2
- FAAH | c.1020G>C p.P340= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV54544220, COSV54544702; called by muse, mutect2, varscan2
- TPD52 | c.45G>A p.P15= | Silent (SNP) | VAF 64/157 reads (41%) | catalogued as rs767727319, COSV66950926; called by muse, mutect2, varscan2
- ZNF613 | c.1059C>T p.F353= (on ENST00000293471 / NM_001031721.4; = p.F317= on NM_024840.4) | Silent (SNP) | VAF 58/165 reads (35%) | catalogued as COSV53272615; called by muse, mutect2, varscan2
- MIR520A | n.78G>A | RNA (SNP) | VAF 81/291 reads (28%) | catalogued as rs534597914; called by muse, mutect2, varscan2
- WASF4P | n.43C>G | RNA (SNP) | VAF 52/130 reads (40%) | called by muse, mutect2, varscan2
